Somatic mutation profile of tumor specimen TCGA-24-1466-01A (aliquot TCGA-24-1466-01A-01W-0545-08) from TCGA case TCGA-24-1466, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.8 years (27,307 days).
Specimen TCGA-24-1466-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93959bfa-3652-4474-b3e8-b6207f518ce7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1466-10A (Blood Derived Normal), aliquot TCGA-24-1466-10A-01W-0545-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0001310d-964e-4c94-bde5-0510e5b76bb9

The open-access MAF lists 71 somatic variants for this specimen: 55 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 14, Frame Shift Ins 3, Frame Shift Del 2, Intron 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 393/477 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADGRF4 | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 220/325 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51952267; called by muse, mutect2, varscan2
- AFF4 | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 171/588 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV54794623, COSV99534431; called by muse, mutect2, varscan2
- AGAP6 | c.784A>G p.K262E (on ENST00000374056 / NM_001365867.1; = p.K285E on NM_001077665.2) | Missense Mutation (SNP) | VAF 168/641 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100929089; called by muse, mutect2, varscan2
- AGL | c.1867G>C p.D623H | Missense Mutation (SNP) | VAF 45/730 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54048508, COSV99649244; called by muse, mutect2
- AKAP9 | c.8278G>T p.V2760F (on ENST00000359028; = p.V2736F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV62345841; called by muse, mutect2, varscan2
- ARHGEF9 | c.71A>T p.N24I | Missense Mutation (SNP) | VAF 186/1151 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as COSV99491814; called by muse, mutect2, varscan2
- AURKB | c.475dup p.R159Pfs*15 | Frame Shift Ins (INS) | VAF 8/90 reads (9%) | catalogued as rs745673717; called by mutect2, pindel
- CCT2 | c.1556A>G p.N519S | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV100167623; called by muse, mutect2, varscan2
- CD1B | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs756984484, COSV63804288; called by muse, mutect2, varscan2
- CDK12 | c.2988A>T p.L996F | Missense Mutation (SNP) | VAF 544/676 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71000615; called by mutect2, varscan2
- CDON | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV54996997, COSV54997745; called by muse, mutect2, varscan2
- CHRD | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770711370, COSV99200357; called by muse, mutect2, varscan2
- COBL | c.2456A>C p.K819T | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54345361; called by muse, mutect2, varscan2
- DENND1B | c.1599-1G>A p.X533_splice | Splice Site (SNP) | VAF 16/62 reads (26%) | catalogued as COSV54148724; called by muse, mutect2
- DLGAP1 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs951699696, COSV59802690; called by muse, mutect2, varscan2
- EPB41L4A | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 82/118 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1297518376, COSV54869264; called by muse, mutect2, varscan2
- FAM83B | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60921955; called by muse, mutect2, varscan2
- FIGNL1 | c.53A>T p.Y18F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV63553486; called by muse, mutect2, varscan2
- FLT4 | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.983); catalogued as COSV56107900; called by muse, mutect2, varscan2
- FRMPD3 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 148/398 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs919379769, COSV99346339; called by muse, mutect2, varscan2
- FRMPD4 | c.917A>G p.E306G | Missense Mutation (SNP) | VAF 162/345 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV66214718, COSV66218639; called by muse, mutect2, varscan2
- GRIK4 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.245); catalogued as rs531010515, COSV101483613; called by muse, mutect2
- GSTM1 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as rs773852055, COSV100564410; called by muse, mutect2, varscan2
- H3C2 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as COSV52517918, COSV52518717; called by muse, mutect2, varscan2
- HMCN1 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV54899482; called by muse, mutect2, varscan2
- IQSEC1 | c.2144A>G p.N715S | Missense Mutation (SNP) | VAF 129/231 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs145903276; called by muse, mutect2, varscan2
- KCNQ5 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 106/446 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781763407, COSV59658177; called by muse, mutect2, varscan2
- KMT2E | c.3683C>G p.S1228C | Missense Mutation (SNP) | VAF 339/730 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV57573130; called by muse, varscan2
- KRTAP10-9 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.556); catalogued as rs782564953, COSV59961652; called by muse, mutect2, varscan2
- LRP1 | c.1722C>G p.Y574* | Nonsense Mutation (SNP) | VAF 28/826 reads (3%) | catalogued as COSV54511107, COSV99675875; called by muse, mutect2
- LRRK1 | c.3697C>G p.L1233V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV52611090; called by muse, mutect2, varscan2
- LYPLA2 | c.626T>C p.M209T | Missense Mutation (SNP) | VAF 103/253 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.049); catalogued as rs774207005, COSV65720660; called by muse, mutect2, varscan2
- MPDZ | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 210/437 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV59941158; called by muse, mutect2, varscan2
- MUC16 | c.25909_25912del p.E8637Kfs*10 | Frame Shift Del (DEL) | VAF 46/516 reads (9%) | catalogued as rs1432203305; called by mutect2, pindel
- NBEA | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769510067, COSV59763993; called by muse, mutect2, varscan2
- NDRG1 | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 74/353 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV60483906; called by muse, mutect2, varscan2
- NEXMIF | c.1998A>C p.K666N | Missense Mutation (SNP) | VAF 42/740 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs1175653711, COSV99280857; called by muse, mutect2
- PALB2 | c.1456A>G p.K486E | Missense Mutation (SNP) | VAF 150/385 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs876658949, COSV55165071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCM1 | c.1297C>G p.Q433E | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs1416275321, COSV61516250; called by muse, mutect2
- PHKA1 | c.1396G>T p.A466S | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.088); catalogued as COSV59805660; called by muse, mutect2, varscan2
- PPP1R3F | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV99278741; called by muse, mutect2, varscan2
- RPL27A | c.427dup p.A143Gfs*18 | Frame Shift Ins (INS) | VAF 10/68 reads (15%) | catalogued as rs764990714; called by mutect2, varscan2
- SGCE | c.578C>T p.P193L (on ENST00000647096; = p.P157L on NM_003919.3) | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs768233445, COSV56017164; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SI | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs768467752, COSV52277838; called by mutect2, varscan2
- SNX20 | c.55T>C p.C19R | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.07); catalogued as COSV56057622; called by muse, mutect2, varscan2
- SPTAN1 | c.6553A>G p.I2185V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); catalogued as rs755436331, COSV63987079; called by muse, mutect2, varscan2
- STS | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 457/1599 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM034300, COSV99481269; called by muse, mutect2, varscan2
- SUV39H2 | c.493C>G p.P165A (on ENST00000354919 / NM_001193424.2; = p.P105A on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/737 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.428); catalogued as COSV57953844; called by muse, mutect2, varscan2
- SZT2 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 36/681 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1395880643, COSV100987282; called by muse, mutect2
- TOX3 | c.389A>C p.H130P | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV99567573; called by muse, mutect2
- ZNF280C | c.880G>T p.V294F | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100921232; called by muse, mutect2
- CREBBP | c.846_852dup p.G285Sfs*67 | Frame Shift Ins (INS) | VAF 142/416 reads (34%) | called by mutect2, varscan2
- MRC1 | c.3697T>A p.S1233T | Missense Mutation (SNP) | VAF 228/1310 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NAV1 | c.1273_1276del p.D425Ifs*29 | Frame Shift Del (DEL) | VAF 666/1213 reads (55%) | called by mutect2, pindel, varscan2
- ACSM2B | c.549G>T p.V183= | Silent (SNP) | VAF 36/937 reads (4%) | catalogued as COSV100312271, COSV100312682; called by muse, mutect2
- ERICH3 | c.4479G>A p.A1493= | Silent (SNP) | VAF 454/1846 reads (25%) | catalogued as rs780847773, COSV58599433; called by muse, mutect2, varscan2
- FLNC | c.6030C>T p.V2010= | Silent (SNP) | VAF 18/191 reads (9%) | catalogued as rs375957769; called by muse, mutect2
- HLA-E | c.249G>A p.R83= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as COSV64927498; called by muse, mutect2
- LAS1L | c.1404C>T p.S468= | Silent (SNP) | VAF 40/166 reads (24%) | catalogued as COSV56707237; called by muse, mutect2, varscan2
- MMP2 | c.1128G>A p.A376= | Silent (SNP) | VAF 116/143 reads (81%) | catalogued as rs768234184, COSV54599409; called by muse, mutect2, varscan2
- MRC1 | c.3900C>T p.F1300= | Silent (SNP) | VAF 80/614 reads (13%) | called by muse, mutect2, varscan2
- NECAP1 | c.663A>G p.G221= | Silent (SNP) | VAF 220/397 reads (55%) | catalogued as COSV60249331; called by muse, mutect2, varscan2
- RASGRP3 | c.1872C>T p.G624= (on ENST00000402538 / NM_001349975.2; = p.G623= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 87/222 reads (39%) | catalogued as rs374245195; called by mutect2, varscan2
- SCN8A | c.4485G>C p.L1495= | Silent (SNP) | VAF 37/117 reads (32%) | catalogued as COSV61981351; called by muse, mutect2, varscan2
- SORBS1 | c.3072A>T p.S1024= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV53357436; called by muse, mutect2, varscan2
- TPK1 | c.624G>C p.V208= | Silent (SNP) | VAF 43/620 reads (7%) | catalogued as COSV100765680; called by muse, mutect2
- TRIM50 | c.312G>A p.Q104= | Silent (SNP) | VAF 7/232 reads (3%) | catalogued as COSV99333969; called by muse, mutect2
- ZNF536 | c.417C>T p.F139= | Silent (SNP) | VAF 30/139 reads (22%) | catalogued as COSV62818509, COSV62823576; called by muse, mutect2, varscan2
- GCNT2 | c.925+26631G>A | Intron (SNP) | VAF 229/961 reads (24%) | catalogued as rs900233332, COSV60233219; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85352G>A | Intron (SNP) | VAF 16/104 reads (15%) | catalogued as rs754460433, COSV72277184; called by muse, mutect2, varscan2
